Somatic mutation profile of tumor specimen MMRF_1932_1_BM_CD138pos (aliquot MMRF_1932_1_BM_CD138pos_T1_KBS5U_L07251) from MMRF case MMRF_1932, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,102 days).
Specimen MMRF_1932_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bb0309b-9f97-4772-a8ee-61bf9705ca8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1932_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1932_1_PB_Whole_C3_KBS5U_L07252; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acadb16f-4050-404d-beb7-f3abcc044421

The open-access MAF lists 88 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 19, Silent 16, Intron 11, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/188 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCC11 | c.2150G>A p.S717N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62323397; called by mutect2, varscan2
- BABAM2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs1219107964; called by muse, mutect2, varscan2
- C1QTNF1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs148307780; called by muse, mutect2, varscan2
- CCDC158 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs1404766270; called by muse, mutect2, varscan2
- CCDC80 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 133/203 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759648511, COSV52815608; called by muse, mutect2, varscan2
- CERKL | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1368635093; called by muse, mutect2, varscan2
- CSRNP1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 107/162 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142034027, COSV104382348; called by muse, mutect2, varscan2
- CUL7 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745425209, COSV54813176; called by muse, mutect2, varscan2
- CYP4F3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs964959320, COSV55407391; called by muse, mutect2, varscan2
- DNAH10 | c.1058C>T p.A353V (on ENST00000409039; = p.A292V on NM_207437.3) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs566391168, COSV101292830; called by muse, mutect2, varscan2
- DSPP | c.279T>G p.F93L | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.089); catalogued as rs763608560; called by muse, mutect2, varscan2
- ICAM5 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778250292; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368166600; called by muse, mutect2, varscan2
- MBD1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 84/139 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274452; called by muse, mutect2, varscan2
- NCKAP5 | c.3791C>A p.P1264Q | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780666011; called by muse, mutect2, varscan2
- PCDH17 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs756164339, COSV64978238; called by muse, mutect2, varscan2
- PROS1 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1386488557; called by muse, mutect2
- ZNF462 | c.6568G>A p.V2190M | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as rs374819141, COSV99472661; called by muse, mutect2, varscan2
- ZNRF3 | c.1441G>T p.E481* (on ENST00000544604 / NM_001206998.2; = p.E381* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | catalogued as COSV100238542; called by muse, mutect2, varscan2
- ACR | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALS2 | c.4693_4695del p.T1565del | In Frame Del (DEL) | VAF 42/96 reads (44%) | called by pindel, varscan2
- CCDC15 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- GLI2 | c.4259G>T p.G1420V (on ENST00000361492 / NM_001374353.1; = p.G1437V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GPAA1 | c.1862A>T p.K621M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTR3B | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPRID1 | c.2419A>G p.I807V | Missense Mutation (SNP) | VAF 115/385 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNA3 | c.914G>C p.W305S | Missense Mutation (SNP) | VAF 64/66 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.634T>C p.C212R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LMTK3 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2
- MUC5AC | c.10594G>T p.V3532L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, varscan2
- NDUFB4 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SDK2 | c.2896A>C p.I966L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SOX9 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT5C | c.278dup p.I94Nfs*16 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- TENT5C | c.895_896del p.E299Rfs*26 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- TET1 | c.1362C>A p.S454R | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ADGB | c.510C>A p.P170= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- CASD1 | c.1179A>G p.E393= | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- COQ7 | c.228G>C p.R76= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV58981527; called by muse, mutect2, varscan2
- EIF3B | c.492C>T p.S164= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs986569973; called by muse, mutect2, varscan2
- ERCC3 | c.1752G>A p.T584= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs755417060; called by muse, mutect2, varscan2
- FAAP100 | c.2409C>T p.A803= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs377147677; called by muse, mutect2, varscan2
- GPR50 | c.417C>T p.I139= | Silent (SNP) | VAF 78/176 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.112A>C p.R38= | Silent (SNP) | VAF 36/182 reads (20%) | called by muse, varscan2
- IGHV3-30 | c.111G>A p.L37= | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, varscan2
- MDGA2 | c.1926C>T p.T642= (on ENST00000399232 / NM_001113498.2; = p.T344= on NM_182830.4) | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs996859247; called by muse, mutect2, varscan2
- MUC5B | c.14553G>A p.P4851= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs758020542; called by muse, mutect2, varscan2
- PDZD2 | c.4968C>T p.Y1656= | Silent (SNP) | VAF 24/368 reads (7%) | catalogued as rs1349133576; called by muse, mutect2
- SIRT7 | c.520C>T p.L174= | Silent (SNP) | VAF 49/77 reads (64%) | called by muse, mutect2, varscan2
- TOPBP1 | c.3930A>G p.G1310= | Silent (SNP) | VAF 60/107 reads (56%) | called by muse, mutect2, varscan2
- UBXN2B | c.882G>A p.A294= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs775165230; called by muse, mutect2, varscan2
- UMODL1 | c.2679C>T p.T893= (on ENST00000408910 / NM_001004416.2; = p.T1021= on NM_173568.3) | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.*1582T>G | 3'UTR (SNP) | VAF 42/61 reads (69%) | called by muse, mutect2
- ADGRA3 | c.1810-783C>T | Intron (SNP) | VAF 78/266 reads (29%) | catalogued as rs1410685331, COSV99293682; called by muse, mutect2, varscan2
- AGO4 | c.*3305T>G | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- ATXN7L2 | c.128-104G>A | Intron (SNP) | VAF 15/34 reads (44%) | catalogued as COSV63992610; called by muse, mutect2
- BCL7A | chr12:122021263 A>T | 5'Flank (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- CRTC3 | c.352-3504A>G | Intron (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- DCLRE1C | c.973-469A>C | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- DCTN4 | c.*831C>T | 3'UTR (SNP) | VAF 17/58 reads (29%) | catalogued as rs188371064; called by muse, mutect2, varscan2
- EBF2 | c.*1441G>A | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2
- EPHA7 | c.*2390C>T | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- EPHB1 | c.*1168A>G | 3'UTR (SNP) | VAF 26/40 reads (65%) | called by muse, mutect2, varscan2
- H3C1 | c.-9T>A | 5'UTR (SNP) | VAF 46/102 reads (45%) | catalogued as rs370504250; called by muse, mutect2, varscan2
- HSPA5 | c.*389_*392del | 3'UTR (DEL) | VAF 39/110 reads (35%) | catalogued as rs1345138222; called by mutect2, pindel, varscan2
- ITSN1 | c.*4838G>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*2241A>C | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- KLK1 | c.497-48G>T | Intron (SNP) | VAF 71/306 reads (23%) | called by muse, mutect2, varscan2
- MGLL | c.*1826A>T | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- NELL1 | c.*312G>C | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- PDE4DIP | c.2815+3652_2815+3653del | Intron (DEL) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- PHOX2B | c.*371T>G | 3'UTR (SNP) | VAF 63/203 reads (31%) | called by muse, mutect2, varscan2
- PTENP1 | n.1289G>C | RNA (SNP) | VAF 83/313 reads (27%) | called by muse, mutect2, varscan2
- PTPN2 | c.1143-98A>G | Intron (SNP) | VAF 43/202 reads (21%) | catalogued as rs75499491; called by muse, mutect2, varscan2
- RPL28 | c.205+222A>C | Intron (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- SF3B1 | c.415+836A>G | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3478+628G>A | Intron (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- SIK1B | c.*1521C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SMCHD1 | c.*210A>T | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- SOX11 | c.*6286A>G | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- TADA2B | c.271-515T>A | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- U2AF1L4 | c.*154C>A | 3'UTR (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- UBXN7 | c.*5475G>T | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- UNC5C | c.*5164A>C | 3'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2
- ZNF606 | chr19:58008344 G>A | 5'Flank (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- ZZEF1 | c.*808T>G | 3'UTR (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
